Somatic mutation profile of tumor specimen TCGA-BQ-7049-01A (aliquot TCGA-BQ-7049-01A-11D-1961-08) from TCGA case TCGA-BQ-7049, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 45.8 years (16,717 days).
Specimen TCGA-BQ-7049-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6278a344-b5d8-4d2b-9c24-050ca11cc9cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7049-11A (Solid Tissue Normal), aliquot TCGA-BQ-7049-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4afad2a8-d0d3-4d1d-b3b0-89f8dc4f0427

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.2638A>C p.K880Q | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV61284164; called by muse, mutect2, varscan2
- ELAVL2 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 76/392 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1475666825, COSV56373178; called by muse, mutect2, varscan2
- EMC10 | c.173A>G p.H58R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs774915076, COSV58541744, COSV58543660; called by muse, mutect2, varscan2
- H2BC4 | c.197T>G p.F66C | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as COSV58417879; called by muse, mutect2
- NLRX1 | c.2354+2T>A p.X785_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as rs779766987, COSV52710789; called by muse, mutect2, varscan2
- OSBPL6 | c.1795C>G p.L599V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51933426; called by muse, mutect2, varscan2
- SCN1A | c.1045T>A p.Y349N | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57692112; called by muse, mutect2, varscan2
- SDHA | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53768962; called by muse, mutect2, varscan2
- UAP1L1 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64307145; called by muse, mutect2, varscan2
- VAT1L | c.1206G>T p.E402D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); catalogued as rs780223836, COSV56830433; called by mutect2, varscan2
- ZNF280A | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV57482770; called by mutect2, varscan2
- ZNF404 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV60989355; called by muse, mutect2
- PLAT | c.1312C>T p.L438= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV54278770; called by muse, mutect2, varscan2
- SYAP1 | c.696T>C p.N232= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV66469150; called by muse, mutect2, varscan2
